Somatic mutation profile of tumor specimen TCGA-OR-A5JQ-01A (aliquot TCGA-OR-A5JQ-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JQ, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 26.5 years (9,667 days).
Specimen TCGA-OR-A5JQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42e5f3b8-6704-46ec-8d4b-d3a62315bc6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JQ-10A (Blood Derived Normal), aliquot TCGA-OR-A5JQ-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbf3e1d8-98a2-4e6a-b78c-2d00c973a15f

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM3 | c.2005G>T p.A669S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1294692941, COSV58641619, COSV58648759; called by muse, mutect2
- CFTR | c.2620-2A>T p.X874_splice | Splice Site (SNP) | VAF 13/213 reads (6%) | called by muse, mutect2
- COL6A6 | c.5213T>A p.V1738E | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- EPHA1 | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LARGE1 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.017); called by muse, mutect2
- ABCA1 | c.4284C>G p.P1428= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs763467216; called by muse, mutect2, varscan2
- OR2J3 | c.273G>A p.P91= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as rs747705634, COSV65849270; called by muse, mutect2
- SCRIB | c.1323G>T p.P441= | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
